Somatic mutation profile of tumor specimen TCGA-EY-A1GE-01A (aliquot TCGA-EY-A1GE-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 67.5 years (24,667 days).
Specimen TCGA-EY-A1GE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27234ce5-48d2-402d-9147-c7e4bff6f03f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GE-10A (Blood Derived Normal), aliquot TCGA-EY-A1GE-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1889149b-d481-448b-8423-809b173929f8

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 15/29 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.6955C>T p.R2319* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | catalogued as rs398123383, CM981166, COSV70341208; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751000395, COSV55116085; called by muse, mutect2, varscan2
- ADGRL1 | c.1649C>T p.A550V (on ENST00000340736 / NM_001008701.3; = p.A545V on NM_014921.5) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as rs776368374, COSV100529908; called by muse, mutect2, varscan2
- ALOX15B | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs773574980, COSV101205747; called by muse, mutect2, varscan2
- ATR | c.2549T>C p.M850T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100638729; called by muse, mutect2, varscan2
- AZI2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV99843808; called by muse, mutect2, varscan2
- BCL7C | c.529-1G>A p.X177_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99288845; called by muse, mutect2, varscan2
- C6orf118 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs201051493, COSV57813406; called by muse, varscan2
- CCDC27 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.877); catalogued as rs139710175; called by muse, mutect2, varscan2
- CDH26 | c.1454C>G p.T485S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99723214; called by muse, mutect2, varscan2
- CENPI | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1010299546, COSV99515983; called by muse, mutect2, varscan2
- CLUH | c.3476A>C p.K1159T (on ENST00000435359; = p.K1198T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV101425942; called by muse, mutect2, varscan2
- DIRAS2 | c.92C>G p.T31R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV101005931; called by muse, mutect2, varscan2
- DMD | c.10496A>G p.E3499G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100630021; called by muse, mutect2, varscan2
- FAM98A | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs144541780; called by muse, mutect2, varscan2
- FBXL5 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV100378137; called by muse, mutect2, varscan2
- FRMD7 | c.1349G>C p.C450S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100049468; called by muse, mutect2, varscan2
- GAL3ST3 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV61749517; called by muse, mutect2, varscan2
- KDM6A | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100938719; called by muse, mutect2, varscan2
- LANCL2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99635287; called by muse, mutect2, varscan2
- MCTP2 | c.1825A>C p.N609H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100537863; called by muse, mutect2, varscan2
- MMP7 | c.365A>C p.H122P | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99497225; called by muse, mutect2, varscan2
- OR2AK2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs758970396, COSV100823199, COSV100824408; called by muse, mutect2, varscan2
- PKD2L2 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV99296828; called by muse, mutect2, varscan2
- SMC1A | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782176647, CM101868, COSV59129751, COSV59132016; called by muse, mutect2, varscan2
- SMURF1 | c.1203C>G p.I401M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV100742736; called by muse, mutect2, varscan2
- SULF1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs780560683, COSV52686698; called by muse, mutect2
- TRPM1 | c.3929A>G p.K1310R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56631169; called by muse, mutect2, varscan2
- UBR5 | c.2151+1G>A p.X717_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99642802; called by muse, mutect2, varscan2
- ZNRF3 | c.733C>T p.R245* (on ENST00000544604 / NM_001206998.2; = p.R145* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs1188411932, COSV60431282; called by muse, mutect2, varscan2
- PTEN | c.848del p.P283Qfs*8 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- RAD21 | c.180dup p.L61Tfs*19 | Frame Shift Ins (INS) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.3840_3850del p.D1280Efs*10 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- ZNF516 | c.799_800dup p.M267Ifs*2 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- B3GNT7 | c.948C>G p.A316= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99806072; called by muse, mutect2, varscan2
- DDX55 | c.1434C>T p.D478= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1380899547, COSV53016113; called by muse, mutect2, varscan2
- FAM199X | c.1083C>T p.L361= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100245580; called by muse, mutect2, varscan2
- ITIH1 | c.639G>A p.P213= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs754271106, COSV56253723; called by muse, mutect2, varscan2
- KLK11 | c.798G>A p.T266= (on ENST00000594768 / NM_144947.3; = p.T234= on NM_006853.3) | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs917443821, COSV100011320, COSV59399492; called by muse, mutect2, varscan2
- PCDHA8 | c.684G>T p.L228= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100971134; called by muse, mutect2, varscan2
- RIT2 | c.636G>A p.K212= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs1019350553, COSV100452106; called by muse, mutect2, varscan2
- SH2D1A | c.129A>T p.L43= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100758377; called by muse, mutect2, varscan2
- TNR | c.693C>T p.S231= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs775081401, COSV54874573; called by muse, mutect2, varscan2
- ZNF641 | c.535A>C p.R179= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99973741; called by muse, mutect2, varscan2
